Somatic mutation profile of tumor specimen C3L-06541-54 (aliquot CPT0358050001) from CPTAC case C3L-06541, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 72.9 years (26,628 days).
Specimen C3L-06541-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b00b8904-79b8-493f-ad20-8443831fbef8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06541-52 (Buccal Cell Normal), aliquot CPT0358030001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2d72404-d47e-49fe-b5c3-253c896f5a9a

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 1, Frame Shift Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 23/70 reads (33%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, varscan2
- KIAA1755 | c.2061G>A p.V687= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs765980240; called by muse, varscan2
- PCDHGA3 | c.2425-67401G>A | Intron (SNP) | VAF 12/284 reads (4%) | called by muse, mutect2
